Somatic mutation profile of tumor specimen TCGA-CV-7253-01A (aliquot TCGA-CV-7253-01A-11D-2012-08) from TCGA case TCGA-CV-7253, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 58.8 years (21,473 days).
Specimen TCGA-CV-7253-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c187df1e-bc8f-40d7-a265-87d3dedb5071.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-7253-10A (Blood Derived Normal), aliquot TCGA-CV-7253-10A-01D-2013-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f9d9c75e-92c2-4978-87be-77ffff5b9e92

The open-access MAF lists 195 somatic variants for this specimen: 152 protein-altering or splice-affecting, 41 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 120, Silent 41, Nonsense Mutation 12, Splice Site 7, Frame Shift Del 5, In Frame Del 4, Frame Shift Ins 3, Intron 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.812A>T p.E271V | Missense Mutation (SNP) | VAF 17/27 reads (63%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM942136, COSV52661418, COSV52925998, COSV53589174; called by muse, mutect2
- A2ML1 | c.3786C>G p.I1262M | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.163); catalogued as COSV100229335; called by muse, mutect2, varscan2
- AC134980.2 | c.683C>A p.A228E | Missense Mutation (SNP) | VAF 28/199 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs1209255401, COSV100171864, COSV60907262; called by muse, mutect2, varscan2
- ACSF2 | c.1256C>T p.A419V | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as rs148600715; called by muse, mutect2, varscan2
- ADCY10 | c.514G>A p.V172M | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100897042; called by muse, mutect2, varscan2
- ADORA1 | c.583C>T p.L195F | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.048); catalogued as rs199949273, COSV55143632; called by muse, mutect2, varscan2
- AK9 | c.5125A>G p.R1709G | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.397); catalogued as COSV101413987; called by muse, mutect2, varscan2
- AKAP6 | c.1550C>T p.S517L | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.122); catalogued as rs781224671, COSV99803796; called by muse, mutect2, varscan2
- AMIGO3 | c.535G>A p.G179S | Missense Mutation (SNP) | VAF 38/70 reads (54%) | SIFT tolerated (0.09); PolyPhen benign (0.369); catalogued as rs373111160, COSV100246730; called by muse, mutect2, varscan2
- AP002512.3 | c.609G>T p.Q203H | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99688100; called by muse, mutect2, varscan2
- ARMCX5 | c.220A>T p.T74S | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT tolerated (0.11); PolyPhen benign (0.054); catalogued as COSV99863535; called by muse, mutect2, varscan2
- ARSK | c.1147C>T p.P383S | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.364); catalogued as rs1306312018, COSV101187566; called by muse, mutect2, varscan2
- ASIC2 | c.476G>A p.R159H | Missense Mutation (SNP) | VAF 40/119 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100726919; called by muse, mutect2, varscan2
- ATP8B2 | c.1973G>T p.R658L (on ENST00000672630; = p.R625L on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100528192; called by muse, mutect2, varscan2
- AUTS2 | c.283A>C p.S95R | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.423); catalogued as COSV100719402; called by muse, mutect2, varscan2
- B3GNT3 | c.349C>T p.P117S | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100592855; called by muse, mutect2, varscan2
- BAG3 | c.1601A>G p.K534R | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as COSV100958288, COSV64842334; called by muse, mutect2, varscan2
- BCL2L2 | c.328A>C p.S110R | Missense Mutation (SNP) | VAF 41/95 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99161634; called by muse, mutect2, varscan2
- C2orf16 | c.5358_5405del p.K1788_E1803del | In Frame Del (DEL) | VAF 60/578 reads (10%) | catalogued as rs1558459997; called by muse*, mutect2
- C6orf58 | c.820A>G p.T274A | Missense Mutation (SNP) | VAF 54/92 reads (59%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as rs771163070, COSV100315031; called by muse, mutect2, varscan2
- CACNA1D | c.5840C>T p.T1947M (on ENST00000350061 / NM_001128840.3; = p.T1967M on NM_000720.4) | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.459); catalogued as rs752102016, COSV55452349; called by muse, mutect2, varscan2
- CACNA1G | c.5144G>C p.R1715P | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM1511857, COSV100662400; called by muse, mutect2, varscan2
- CDC16 | c.103+1G>T p.X35_splice | Splice Site (SNP) | VAF 21/77 reads (27%) | catalogued as COSV99373113; called by muse, mutect2, varscan2
- CDH11 | c.228+1G>T p.X76_splice | Splice Site (SNP) | VAF 19/35 reads (54%) | catalogued as COSV99219564; called by muse, mutect2, varscan2
- CEMIP | c.2945G>A p.R982Q | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.286); catalogued as rs377151951; called by muse, mutect2, varscan2
- CEMIP2 | c.3047C>T p.P1016L | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as rs375145196; called by muse, mutect2, varscan2
- CEP192 | c.4204C>T p.R1402C | Missense Mutation (SNP) | VAF 49/63 reads (78%) | SIFT deleterious (0); PolyPhen benign (0.286); catalogued as rs563248173, COSV100381938; called by muse, mutect2, varscan2
- CERS5 | c.484C>T p.L162F | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV58189162; called by muse, mutect2
- CFH | c.646A>G p.I216V | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.039); catalogued as COSV100661609; called by muse, mutect2, varscan2
- CLDN23 | c.545C>T p.A182V | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs1452231517, COSV67731530; called by muse, mutect2, varscan2
- CNGB1 | c.534+2T>C p.X178_splice | Splice Site (SNP) | VAF 17/50 reads (34%) | catalogued as COSV99208517; called by muse, mutect2, varscan2
- COL4A6 | c.3398G>C p.G1133A | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100564918; called by muse, mutect2, varscan2
- COLGALT2 | c.991G>C p.V331L | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV100730837; called by muse, mutect2, varscan2
- CROT | c.1618G>T p.V540F | Missense Mutation (SNP) | VAF 46/112 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1480384053, COSV100519655; called by muse, mutect2, varscan2
- CRPPA | c.571G>A p.V191I | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs757165158, COSV101235451, COSV101235462; called by muse, mutect2, varscan2
- CSMD3 | c.3286A>T p.T1096S (on ENST00000297405 / NM_001363185.1; = p.T992S on NM_052900.3) | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); catalogued as COSV99845294; called by muse, mutect2, varscan2
- CTCF | c.1067G>T p.C356F | Missense Mutation (SNP) | VAF 87/225 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50535898; called by muse, mutect2, varscan2
- DMXL1 | c.371G>A p.R124H | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as rs547590187, COSV100223543; called by muse, mutect2, varscan2
- DNAH10 | c.9025C>T p.P3009S (on ENST00000409039; = p.P2948S on NM_207437.3) | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101292548; called by muse, mutect2, varscan2
- DNAH8 | c.6998C>T p.P2333L | Missense Mutation (SNP) | VAF 25/30 reads (83%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); catalogued as COSV100546904; called by muse, mutect2, varscan2
- DNAH9 | c.2245G>T p.V749F | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV99307679; called by muse, mutect2
- EEA1 | c.2597C>G p.S866C | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV100468357; called by muse, mutect2, varscan2
- EIF3A | c.2873C>A p.P958H | Missense Mutation (SNP) | VAF 49/177 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); catalogued as COSV100974774; called by muse, mutect2, varscan2
- ERCC6 | c.3550A>G p.K1184E | Missense Mutation (SNP) | VAF 68/170 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.311); catalogued as COSV100876136; called by muse, mutect2, varscan2
- ERCC6L2 | c.895C>T p.L299F | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); catalogued as COSV56633432; called by muse, mutect2, varscan2
- ESM1 | c.386G>A p.C129Y | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101195706; called by muse, mutect2, varscan2
- ESRP2 | c.1634A>T p.E545V (on ENST00000565858 / NM_001365264.1; = p.E535V on NM_024939.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.93); catalogued as COSV99251451; called by muse, mutect2, varscan2
- F11R | c.535A>T p.S179C | Missense Mutation (SNP) | VAF 47/113 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.517); catalogued as COSV99231248; called by muse, mutect2, varscan2
- FRY | c.4867dup p.L1623Pfs*3 | Frame Shift Ins (INS) | VAF 37/96 reads (39%) | catalogued as rs754580696; called by mutect2, pindel, varscan2
- FSCB | c.325C>A p.P109T | Missense Mutation (SNP) | VAF 46/147 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as rs777029779, COSV100469110, COSV100469762; called by muse, mutect2, varscan2
- GABRB2 | c.864C>G p.I288M | Missense Mutation (SNP) | VAF 47/135 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50927679, COSV99196501; called by muse, mutect2, varscan2
- GATA3 | c.149T>A p.L50H | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV100651204; called by muse, mutect2, varscan2
- GFOD1 | c.818C>T p.P273L | Missense Mutation (SNP) | VAF 33/49 reads (67%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs552590164, COSV101015222; called by muse, mutect2, varscan2
- GLUD2 | c.1091C>A p.A364E | Missense Mutation (SNP) | VAF 88/122 reads (72%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV100047051; called by muse, mutect2, varscan2
- GNPTAB | c.2887C>G p.R963G | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100172326; called by muse, mutect2, varscan2
- GSTK1 | c.144G>A p.M48I | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.144); catalogued as COSV100621835; called by muse, mutect2, varscan2
- HABP2 | c.950G>A p.G317D | Missense Mutation (SNP) | VAF 7/115 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100668080; called by muse, mutect2
- HIPK4 | c.1621C>T p.R541* | Nonsense Mutation (SNP) | VAF 39/120 reads (33%) | catalogued as rs1210868555, COSV99396998; called by muse, mutect2, varscan2
- HMGCLL1 | c.928G>A p.G310S | Missense Mutation (SNP) | VAF 39/83 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99233049; called by muse, mutect2, varscan2
- IGFN1 | c.3517G>T p.E1173* (on ENST00000295591 / NM_001367841.1; = p.E3630* on NM_001164586.2) | Nonsense Mutation (SNP) | VAF 65/164 reads (40%) | catalogued as rs375211075, COSV99813399; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IGHV1-2 | c.258G>A p.W86* | Nonsense Mutation (SNP) | VAF 68/317 reads (21%) | catalogued as rs1061866; called by muse, mutect2, varscan2
- IGKV1-16 | c.346T>A p.Y116N | Missense Mutation (SNP) | VAF 60/155 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs1449799614; called by muse, mutect2, varscan2
- ILDR2 | c.1004C>G p.T335S | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.985); catalogued as COSV99614348; called by muse, mutect2, varscan2
- ITPRID1 | c.1819G>C p.D607H | Missense Mutation (SNP) | VAF 43/140 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV60070913, COSV60076380; called by muse, mutect2, varscan2
- KAT6B | c.4435G>A p.V1479I | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.084); catalogued as rs775255115, COSV54749915; called by muse, mutect2, varscan2
- KCNK9 | c.555C>G p.S185R | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.516); catalogued as COSV100271579; called by muse, mutect2, varscan2
- KDM6A | c.3285-1G>A p.X1095_splice | Splice Site (SNP) | VAF 8/10 reads (80%) | catalogued as COSV100938529; called by muse, mutect2, varscan2
- KHDC4 | c.761G>T p.G254V | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100850847; called by muse, mutect2, varscan2
- KIF21B | c.103C>T p.P35S | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.492); catalogued as COSV100145022, COSV104407066; called by muse, mutect2
- KIF3B | c.1418A>C p.K473T | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV100996534; called by muse, mutect2, varscan2
- KPRP | c.455A>T p.N152I | Missense Mutation (SNP) | VAF 49/156 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV100908777; called by muse, mutect2, varscan2
- LINGO1 | c.379C>T p.R127C | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.316); catalogued as rs920818090, COSV62436811; called by muse, mutect2, varscan2
- LRP1B | c.11305T>G p.C3769G | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101259955; called by muse, mutect2, varscan2
- LRPPRC | c.3005A>T p.E1002V | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as COSV99581352; called by muse, mutect2, varscan2
- MACO1 | c.1311C>A p.N437K | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.828); catalogued as COSV100975280; called by muse, mutect2, varscan2
- MATN2 | c.1223T>A p.L408Q | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.954); catalogued as COSV99646985; called by muse, mutect2, varscan2
- MBNL1 | c.743A>C p.K248T | Missense Mutation (SNP) | VAF 151/304 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99221150; called by muse, mutect2, varscan2
- MECOM | c.2722A>G p.I908V (on ENST00000468789 / NM_001105078.4; = p.I1096V on NM_004991.4) | Missense Mutation (SNP) | VAF 37/256 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV99245235; called by muse, mutect2, varscan2
- MPO | c.1056C>A p.N352K | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV99832967; called by muse, mutect2, varscan2
- MRGPRX2 | c.583T>G p.F195V | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.817); catalogued as COSV100316825; called by muse, mutect2, varscan2
- MYO18A | c.3569G>A p.R1190K | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs770435949, COSV100572621; called by muse, mutect2, varscan2
- NAA16 | c.130G>T p.E44* | Nonsense Mutation (SNP) | VAF 9/31 reads (29%) | catalogued as COSV101038407; called by muse, mutect2, varscan2
- NEB | c.5699A>G p.Y1900C | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99427018; called by muse, mutect2, varscan2
- NEFM | c.845A>G p.D282G | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.018); catalogued as COSV99647532; called by muse, mutect2
- NYNRIN | c.2500G>T p.V834L | Missense Mutation (SNP) | VAF 55/124 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV101230676; called by muse, mutect2, varscan2
- OBSL1 | c.5284G>A p.A1762T | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.5); PolyPhen benign (0.27); catalogued as COSV99523153; called by muse, mutect2
- OGFOD3 | c.887G>T p.G296V | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100234535; called by muse, mutect2
- OGFOD3 | c.886G>T p.G296C | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100234536; called by muse, mutect2, varscan2
- OSTM1 | c.44C>A p.P15Q | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.039); catalogued as COSV99514285; called by muse, mutect2, varscan2
- PAX1 | c.1564del p.Y522Ifs*6 | Frame Shift Del (DEL) | VAF 13/52 reads (25%) | catalogued as rs1480754738; called by mutect2, pindel, varscan2
- PIAS2 | c.1000G>T p.E334* | Nonsense Mutation (SNP) | VAF 27/52 reads (52%) | catalogued as COSV100245502; called by muse, mutect2, varscan2
- PLCB4 | c.2005G>T p.G669* | Nonsense Mutation (SNP) | VAF 13/51 reads (25%) | catalogued as COSV99596710; called by muse, mutect2, varscan2
- PRMT8 | c.748A>G p.I250V | Missense Mutation (SNP) | VAF 18/324 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV99713658; called by muse, mutect2
- PROSER1 | c.776-1G>C p.X259_splice | Splice Site (SNP) | VAF 8/32 reads (25%) | catalogued as COSV100612996; called by muse, mutect2, varscan2
- PRR12 | c.2284C>T p.R762C (on ENST00000615927; = p.R1583C on NM_020719.3) | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs1181920855, COSV69817000; called by muse, mutect2
- PTGS2 | c.1113T>G p.Y371* | Nonsense Mutation (SNP) | VAF 47/110 reads (43%) | catalogued as COSV100821836; called by muse, mutect2, varscan2
- RAET1G | c.289G>T p.V97L | Missense Mutation (SNP) | VAF 46/194 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.084); catalogued as COSV100951691; called by muse, mutect2, varscan2
- RAPGEF6 | c.346A>T p.I116F | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99727646; called by muse, mutect2, varscan2
- RELN | c.10274T>C p.V3425A | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV100634654; called by muse, mutect2, varscan2
- RELN | c.7465G>A p.G2489R | Missense Mutation (SNP) | VAF 45/112 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100634657; called by muse, mutect2, varscan2
- RER1 | c.187G>A p.G63S | Missense Mutation (SNP) | VAF 9/115 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs751035650, COSV100087983; called by muse, mutect2
- RRP36 | c.665T>A p.L222Q | Missense Mutation (SNP) | VAF 199/496 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99763901; called by muse, mutect2, varscan2
- RSPH9 | c.259C>A p.P87T | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.118); catalogued as COSV100937866; called by muse, mutect2, varscan2
- RSRP1 | c.316C>T p.R106W | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs750442247, COSV99682713; called by muse, mutect2, varscan2
- SCARA5 | c.896G>A p.R299Q | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.289); catalogued as rs762375303, COSV100108049; called by muse, mutect2, varscan2
- SEC31B | c.3328G>T p.E1110* | Nonsense Mutation (SNP) | VAF 12/34 reads (35%) | catalogued as COSV100649114; called by muse, mutect2, varscan2
- SH3BP4 | c.370A>G p.M124V | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV100749285; called by muse, mutect2, varscan2
- SHB | c.745C>T p.P249S | Missense Mutation (SNP) | VAF 41/115 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100891084; called by muse, mutect2, varscan2
- SLC19A3 | c.494C>T p.A165V | Missense Mutation (SNP) | VAF 49/144 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.627); catalogued as rs144223086, COSV99295779; called by muse, mutect2, varscan2
- SLC22A9 | c.207A>T p.Q69H | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.03); catalogued as rs1460351976, COSV99655321; called by muse, mutect2, varscan2
- SLC41A2 | c.830T>A p.L277H | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99316864; called by muse, mutect2, varscan2
- SLC4A4 | c.660C>A p.N220K (on ENST00000264485 / NM_001098484.3; = p.N176K on NM_003759.4) | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT tolerated (0.94); PolyPhen benign (0.425); catalogued as COSV99141846; called by muse, mutect2, varscan2
- SMARCA4 | c.419C>A p.S140Y | Missense Mutation (SNP) | VAF 31/54 reads (57%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as COSV100759057; called by muse, mutect2, varscan2
- SPG11 | c.1528A>T p.S510C | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99969386; called by muse, varscan2
- SUGP2 | c.1742G>A p.R581Q | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.86); catalogued as COSV58260761; called by muse, mutect2, varscan2
- SVEP1 | c.8309G>T p.C2770F | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99929623; called by muse, mutect2
- SYNE1 | c.21710T>C p.L7237P (on ENST00000367255 / NM_182961.4; = p.L7166P on NM_033071.3) | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99575905; called by muse, mutect2, varscan2
- TANC1 | c.1352-1G>T p.X451_splice | Splice Site (SNP) | VAF 30/88 reads (34%) | catalogued as COSV99714994; called by muse, mutect2, varscan2
- TAOK1 | c.2304A>T p.L768F | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99914610; called by muse, mutect2, varscan2
- TCP11 | c.694G>T p.E232* (on ENST00000512012; = p.E170* on NM_018679.5) | Nonsense Mutation (SNP) | VAF 99/398 reads (25%) | catalogued as COSV55136441, COSV99774255; called by muse, mutect2, varscan2
- TGFB1I1 | c.471G>T p.E157D (on ENST00000394863 / NM_001042454.3; = p.E140D on NM_015927.4) | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as COSV100691210; called by muse, mutect2, varscan2
- TMEM174 | c.250A>T p.T84S | Missense Mutation (SNP) | VAF 46/136 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.637); catalogued as COSV99703800; called by muse, mutect2, varscan2
- TMEM94 | c.845A>G p.H282R | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV100050831; called by muse, mutect2, varscan2
- TNXB | c.5182A>G p.T1728A (on ENST00000647633; = p.T1481A on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.224); catalogued as rs1353187688, COSV100926575; called by mutect2, varscan2
- TRGV5 | c.206A>G p.D69G | Missense Mutation (SNP) | VAF 52/118 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.709); catalogued as rs1405221015; called by muse, mutect2, varscan2
- TTC23L | c.1011G>T p.E337D | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as COSV101533381; called by muse, mutect2, varscan2
- VCP | c.1676T>G p.V559G | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100734331; called by muse, mutect2, varscan2
- WDR35 | c.2089C>T p.R697* (on ENST00000345530 / NM_001006657.2; = p.R686* on NM_020779.4) | Nonsense Mutation (SNP) | VAF 23/157 reads (15%) | catalogued as rs746421382, COSV55602146; called by muse, mutect2, varscan2
- WDR91 | c.1454A>C p.N485T | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.83); PolyPhen possibly damaging (0.907); catalogued as COSV100615812; called by muse, mutect2, varscan2
- XRCC5 | c.1284A>C p.E428D | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV101079834; called by muse, mutect2, varscan2
- XYLB | c.1451G>A p.G484E | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV99264463; called by muse, mutect2, varscan2
- YPEL5 | c.98C>T p.T33I | Missense Mutation (SNP) | VAF 21/156 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.879); catalogued as rs768956537, COSV99745320; called by muse, mutect2, varscan2
- ZDHHC6 | c.816T>A p.F272L | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV101024449; called by muse, mutect2
- ZFP36 | c.859C>A p.P287T (on ENST00000594442; = p.P281T on NM_003407.5) | Missense Mutation (SNP) | VAF 30/123 reads (24%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.77); catalogued as rs1030508872, COSV99953842, COSV99953965; called by muse, mutect2, varscan2
- ZNF117 | c.970A>T p.K324* | Nonsense Mutation (SNP) | VAF 23/62 reads (37%) | catalogued as COSV51426889, COSV99276022; called by muse, mutect2, varscan2
- ZNF232 | c.725C>A p.S242* | Nonsense Mutation (SNP) | VAF 31/46 reads (67%) | catalogued as COSV100005787; called by muse, mutect2, varscan2
- ZNF451 | c.484A>C p.T162P | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.075); catalogued as COSV100675055; called by muse, mutect2, varscan2
- ZNF608 | c.272C>G p.S91C | Missense Mutation (SNP) | VAF 4/71 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as COSV100102324, COSV60441885; called by muse, mutect2
- ZNF676 | c.619G>T p.G207C (on ENST00000650058; = p.G175C on NM_001001411.3) | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as COSV101236314; called by muse, mutect2, varscan2
- ZNF704 | c.1202G>C p.C401S | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100589800; called by muse, mutect2, varscan2
- ZNHIT6 | c.1070C>A p.A357D | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV100995710; called by muse, mutect2, varscan2
- CELSR2 | c.3040_3042del p.L1014del | In Frame Del (DEL) | VAF 20/90 reads (22%) | called by mutect2, pindel, varscan2
- CEPT1 | c.1124_1125del p.I375Sfs*8 | Frame Shift Del (DEL) | VAF 23/95 reads (24%) | called by mutect2, pindel, varscan2
- CLSPN | c.2473-4_2491del p.X825_splice | Splice Site (DEL) | VAF 46/204 reads (23%) | called by mutect2, pindel
- CMBL | c.352_357del p.K118_Q119del | In Frame Del (DEL) | VAF 5/32 reads (16%) | called by mutect2, pindel
- G6PC | c.327_328del p.C109* | Frame Shift Del (DEL) | VAF 29/101 reads (29%) | called by pindel, varscan2
- NCOR1 | c.435G>A p.K145= | Splice Region (SNP) | VAF 9/12 reads (75%) | called by muse, mutect2
- NSD1 | c.3258_3264del p.S1086Rfs*6 | Frame Shift Del (DEL) | VAF 71/96 reads (74%) | called by mutect2, pindel, varscan2
- RASA3 | c.143dup p.R49Qfs*20 | Frame Shift Ins (INS) | VAF 26/107 reads (24%) | called by mutect2, pindel, varscan2
- RPN2 | c.1445_1468del p.Y482_T489del | In Frame Del (DEL) | VAF 8/48 reads (17%) | called by mutect2, pindel
- TNR | c.560del p.G187Afs*78 | Frame Shift Del (DEL) | VAF 18/145 reads (12%) | called by mutect2, pindel, varscan2
- TRPS1 | c.1573dup p.C525Lfs*5 (on ENST00000220888 / NM_001330599.2; = p.C538Lfs*5 on NM_014112.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 107/198 reads (54%) | called by mutect2, pindel, varscan2
- ACTL7B | c.678G>A p.G226= | Silent (SNP) | VAF 16/72 reads (22%) | catalogued as COSV101012575; called by muse, mutect2, varscan2
- ACY3 | c.609G>A p.L203= | Silent (SNP) | VAF 65/190 reads (34%) | catalogued as COSV99663130; called by muse, mutect2, varscan2
- ADAMTS12 | c.3186G>A p.L1062= | Silent (SNP) | VAF 29/77 reads (38%) | catalogued as COSV100711571, COSV61257497; called by muse, mutect2, varscan2
- ADAMTS19 | c.1992C>T p.R664= | Silent (SNP) | VAF 45/142 reads (32%) | catalogued as COSV99180225; called by muse, mutect2, varscan2
- AMER3 | c.2328G>A p.Q776= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as rs748099038, COSV58471554; called by muse, mutect2, varscan2
- APLF | c.1266C>G p.P422= | Silent (SNP) | VAF 6/55 reads (11%) | catalogued as COSV100376975; called by muse, mutect2, varscan2
- BCL9 | c.1515C>T p.H505= | Silent (SNP) | VAF 46/153 reads (30%) | catalogued as rs782720985, COSV52346478, COSV52347304; called by muse, mutect2, varscan2
- BYSL | c.804C>T p.L268= | Silent (SNP) | VAF 31/112 reads (28%) | catalogued as COSV100026925; called by muse, mutect2, varscan2
- CACNA1C | c.3999C>A p.V1333= | Silent (SNP) | VAF 34/93 reads (37%) | catalogued as COSV100221721; called by muse, mutect2, varscan2
- CCDC85A | c.363G>A p.R121= | Silent (SNP) | VAF 19/80 reads (24%) | catalogued as COSV101339536; called by muse, mutect2, varscan2
- CHRNA3 | c.693C>A p.I231= | Silent (SNP) | VAF 23/52 reads (44%) | catalogued as COSV100468585; called by muse, mutect2, varscan2
- CNOT1 | c.5223G>A p.Q1741= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as COSV99801040; called by muse, mutect2, varscan2
- CSMD1 | c.5055C>T p.T1685= (on ENST00000520002; = p.T1684= on NM_033225.6) | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as rs370545458; called by muse, mutect2, varscan2
- CUX1 | c.2895C>A p.I965= | Silent (SNP) | VAF 10/113 reads (9%) | catalogued as COSV99471118; called by muse, mutect2
- FAM237A | c.249G>A p.E83= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as rs778818897, COSV101405598, COSV69304999; called by muse, mutect2, varscan2
- GRSF1 | c.579G>A p.R193= | Silent (SNP) | VAF 19/81 reads (23%) | catalogued as COSV99635996; called by muse, mutect2, varscan2
- INTS3 | c.3111G>A p.V1037= | Silent (SNP) | VAF 43/122 reads (35%) | catalogued as COSV99670122; called by muse, mutect2, varscan2
- KIF1A | c.5046G>A p.G1682= (on ENST00000320389 / NM_001379639.1; = p.G1674= on NM_004321.8 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as rs369259122; called by muse, mutect2, varscan2
- LRP1 | c.6486C>T p.A2162= | Silent (SNP) | VAF 20/52 reads (38%) | called by muse, mutect2
- MANEA | c.972T>C p.F324= | Silent (SNP) | VAF 18/30 reads (60%) | catalogued as COSV100721646; called by muse, mutect2, varscan2
- MAP3K12 | c.1131G>A p.E377= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as rs1381445488, COSV99913502; called by muse, mutect2, varscan2
- MYO15A | c.10251C>T p.S3417= | Silent (SNP) | VAF 4/37 reads (11%) | catalogued as COSV99234168; called by muse, mutect2, varscan2
- MYO7B | c.6111C>T p.L2037= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as COSV100264945; called by muse, mutect2, varscan2
- NLRP5 | c.2247C>T p.S749= | Silent (SNP) | VAF 21/340 reads (6%) | catalogued as rs149649207; ClinVar: likely benign; called by muse, mutect2
- OBSL1 | c.3162G>A p.E1054= | Silent (SNP) | VAF 32/148 reads (22%) | catalogued as COSV99217381; called by muse, mutect2, varscan2
- OVCA2 | c.24G>A p.R8= | Silent (SNP) | VAF 13/17 reads (76%) | catalogued as COSV99559448, COSV99559634; called by muse, mutect2, varscan2
- PCDHB16 | c.2112G>A p.S704= | Silent (SNP) | VAF 18/352 reads (5%) | catalogued as COSV53374272; called by muse, mutect2
- POSTN | c.822C>A p.P274= | Silent (SNP) | VAF 20/76 reads (26%) | catalogued as COSV101123466, COSV65713351; called by muse, mutect2, varscan2
- RCN3 | c.975C>T p.H325= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as rs149927163; called by muse, mutect2, varscan2
- RGS7 | c.513A>T p.A171= | Silent (SNP) | VAF 15/184 reads (8%) | catalogued as COSV100470383; called by muse, mutect2
- RNF10 | c.2292C>T p.S764= | Silent (SNP) | VAF 103/252 reads (41%) | catalogued as COSV100378921; called by muse, mutect2, varscan2
- SHROOM3 | c.3228C>T p.P1076= | Silent (SNP) | VAF 11/22 reads (50%) | catalogued as rs768793752, COSV99935140; called by muse, mutect2, varscan2
- TMCO1 | c.246C>T p.Y82= (on ENST00000612311 / NM_001256164.1; = p.Y31= on NM_019026.6) | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as COSV100903194; called by muse, mutect2, varscan2
- TMEM120B | c.174G>A p.K58= | Silent (SNP) | VAF 32/77 reads (42%) | catalogued as rs764687480, COSV100699696; called by muse, mutect2, varscan2
- TRAP1 | c.1077G>A p.L359= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV99893856; called by muse, mutect2, varscan2
- TTN | c.12609T>C p.T4203= (on ENST00000591111; = p.T4157= on NM_003319.4) | Silent (SNP) | VAF 40/146 reads (27%) | catalogued as COSV100626571; called by muse, mutect2, varscan2
- USP12 | c.870A>G p.S290= | Silent (SNP) | VAF 18/67 reads (27%) | catalogued as COSV56655269, COSV99997773; called by muse, mutect2, varscan2
- USP45 | c.2445A>G p.*815= | Silent (SNP) | VAF 18/30 reads (60%) | catalogued as COSV100569896; called by muse, mutect2, varscan2
- ZBP1 | c.480A>G p.K160= | Silent (SNP) | VAF 59/191 reads (31%) | catalogued as COSV100473839; called by muse, mutect2, varscan2
- ZFP14 | c.96G>A p.R32= | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as COSV99525289; called by muse, mutect2, varscan2
- ZZEF1 | c.3591T>C p.D1197= | Silent (SNP) | VAF 90/164 reads (55%) | catalogued as rs377636730; called by muse, mutect2, varscan2
- ST3GAL5 | c.319-44T>A | Intron (SNP) | VAF 147/382 reads (38%) | catalogued as COSV100088693; called by muse, mutect2, varscan2
- TMBIM6 | c.-31+589G>T | Intron (SNP) | VAF 9/35 reads (26%) | catalogued as rs766617632, COSV99920837; called by muse, mutect2, varscan2
